Somatic mutation profile of tumor specimen TCGA-BJ-A28R-01A (aliquot TCGA-BJ-A28R-01A-11D-A16O-08) from TCGA case TCGA-BJ-A28R, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.5 years (14,044 days).
Specimen TCGA-BJ-A28R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cb69cc7-defa-45e0-ac3a-8d850f22af7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A28R-10A (Blood Derived Normal), aliquot TCGA-BJ-A28R-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9067b13c-0c8f-466a-b5b3-d8b33ed33baa

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATMIN | c.1966C>G p.L656V | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100214813; called by muse, mutect2
- SCN10A | c.3788G>C p.R1263P | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV71860936, COSV71862013; called by muse, mutect2
- TPM3 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV55137353; called by muse, mutect2, varscan2
- YEATS2 | c.3344C>T p.T1115I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV59368247; called by muse, mutect2, varscan2
- BRICD5 | c.315G>A p.A105= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs368580516; called by muse, mutect2, varscan2
- KCNV2 | c.936C>T p.F312= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs1006319872, COSV66056740; called by muse, mutect2
